FM case AD17962 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/0fc9c080-eb12-43ef-b080-329a404aaeed

Female, 66.4 years: Lobular carcinoma, NOS (ICD-O-3 8520/3) of the breast; metastasis biopsied or resected from the endometrium. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
